Somatic mutation profile of tumor specimen ALCH-ADRV-TTP1-A (aliquot ALCH-ADRV-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADRV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.8 years (25,491 days).
Specimen ALCH-ADRV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9028e681-95e6-40d8-aef8-367ef20fa0d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADRV-NB1-A (Blood Derived Normal), aliquot ALCH-ADRV-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4572eb6e-2557-4fa8-b870-cb12f7a157ea

The open-access MAF lists 303 somatic variants for this specimen: 211 protein-altering or splice-affecting, 62 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 62, Nonsense Mutation 16, Intron 15, Frame Shift Del 6, 5'Flank 4, 3'UTR 3, In Frame Del 3, RNA 3, 3'Flank 3, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APP | c.2149G>C p.V717L | Missense Mutation (SNP) | VAF 67/680 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs63750264, CM003587, CM910040, CM910041, COSV100696097; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.3002C>G p.S1001* | Nonsense Mutation (SNP) | VAF 30/492 reads (6%) | catalogued as rs1555283001; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 97/307 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.2975A>T p.Y992F | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM158898; called by muse, mutect2
- ADK | c.859G>C p.D287H (on ENST00000286621; = p.D270H on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/666 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54214567; called by muse, mutect2
- AKAP6 | c.5099G>T p.C1700F | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772281229; called by muse, mutect2, varscan2
- ANKRD30A | c.1307C>A p.S436Y (on ENST00000611781; = p.S380Y on NM_052997.2) | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.272); catalogued as COSV64617464; called by muse, mutect2
- ANKS1B | c.1958T>C p.I653T | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs760851661; called by muse, mutect2, varscan2
- APOB | c.12742G>C p.D4248H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV104373675; called by muse, mutect2, varscan2
- APOBEC3D | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as rs766832519, COSV53326271; called by mutect2, varscan2
- ARHGAP22 | c.1535G>T p.W512L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as COSV50933067; called by muse, mutect2
- ARRDC4 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as rs562762356; called by muse, mutect2, varscan2
- ATP9A | c.1480G>T p.V494L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs764422261, COSV58769096; called by muse, varscan2
- C3 | c.2834G>C p.R945P | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.595); catalogued as COSV55574082, COSV55581279; called by muse, mutect2, varscan2
- CFHR5 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 203/888 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs758371568; called by muse, mutect2, varscan2
- CFLAR | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778008665; called by muse, mutect2
- CHD3 | c.3415G>A p.G1139R | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV57874530; called by muse, mutect2
- COL1A2 | c.3320G>T p.G1107V | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1282531088; called by muse, mutect2, varscan2
- COL22A1 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as rs758355984; called by muse, mutect2, varscan2
- DNAH11 | c.6382C>T p.R2128W | Missense Mutation (SNP) | VAF 53/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765958695; called by muse, mutect2
- DNAJC5B | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 137/943 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52538530; called by muse, mutect2, varscan2
- EGFLAM | c.2696G>C p.G899A (on ENST00000354891 / NM_001205301.2; = p.G891A on NM_152403.4) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380505; called by muse, mutect2, varscan2
- FBN1 | c.7540G>T p.G2514* | Nonsense Mutation (SNP) | VAF 203/975 reads (21%) | catalogued as CM025900, CM077253, COSV57326105; called by muse, mutect2, varscan2
- FOXI1 | c.177del p.N60Tfs*11 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV60388686; called by mutect2, pindel, varscan2
- FZD2 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779319509, COSV100190425; called by muse, mutect2
- GABRA6 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331513513; called by muse, mutect2
- GNPDA2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs762627150, COSV54948501; called by muse, mutect2
- HDAC4 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs763782479, COSV61863686; called by muse, mutect2, varscan2
- HECW2 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 79/367 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.257); catalogued as COSV53665233; called by muse, mutect2, varscan2
- KEAP1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KLHDC7A | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163496585; called by mutect2, varscan2
- KREMEN1 | c.880G>A p.V294I (on ENST00000407188; = p.V296I on NM_032045.5) | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs1468248789; called by muse, mutect2, varscan2
- LRP1B | c.12848A>T p.N4283I | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.185); catalogued as rs759986287; called by muse, mutect2, varscan2
- LRRK2 | c.5501C>T p.A1834V | Missense Mutation (SNP) | VAF 94/616 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as rs1204418744; called by muse, mutect2, varscan2
- MAST2 | c.4519G>A p.D1507N | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as rs1018347555, COSV53105331; called by muse, mutect2
- MDGA1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs546191944, COSV51801988; called by mutect2, varscan2
- METTL8 | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1017260954; called by muse, mutect2
- MOCS1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 34/386 reads (9%) | catalogued as rs1266681695, CM111815, COSV57935999; called by muse, mutect2
- MYH15 | c.5454G>A p.M1818I | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV56305301; called by muse, mutect2, varscan2
- NOC3L | c.600A>G p.I200M | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV64930308; called by muse, mutect2
- OR4K17 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 157/520 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV59648763; called by muse, mutect2, varscan2
- OR9Q2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs746060364, COSV61111404; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 58/619 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV50564677, COSV50581609; called by muse, mutect2
- PHF3 | c.4949G>A p.R1650K | Missense Mutation (SNP) | VAF 42/565 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.732); catalogued as COSV100012790, COSV100012868; called by muse, mutect2
- PRDM8 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.879); catalogued as rs1326967807; called by muse, mutect2, varscan2
- RACGAP1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV100408022; called by muse, mutect2, varscan2
- RYR2 | c.11773C>T p.Q3925* | Nonsense Mutation (SNP) | VAF 59/288 reads (20%) | catalogued as CM097965, COSV63686899; called by muse, mutect2, varscan2
- RYR2 | c.13646G>T p.S4549I | Missense Mutation (SNP) | VAF 132/615 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV63693442; called by muse, mutect2, varscan2
- SAMD14 | c.1211G>A p.R404Q (on ENST00000330175 / NM_001257359.2; = p.R432Q on NM_174920.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs747590081; called by muse, mutect2, varscan2
- SDHAF1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.87); catalogued as rs1367583912; called by muse, mutect2
- SF3A1 | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV53169192; called by muse, varscan2
- TET2 | c.1836dup p.G613Wfs*25 | Frame Shift Ins (INS) | VAF 28/246 reads (11%) | catalogued as rs1480674896; called by mutect2, varscan2
- TNKS2 | c.1247_1249del p.V416del | In Frame Del (DEL) | VAF 36/342 reads (11%) | catalogued as rs1369138259; called by pindel, varscan2
- XPNPEP2 | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV64369352; called by muse, mutect2, varscan2
- ZIC1 | c.248C>A p.P83Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV99292259; called by mutect2, varscan2
- ZNF324B | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs1339782507; called by muse, mutect2
- ZNF382 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1475243469; called by muse, mutect2
- ZNF530 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60531990; called by muse, mutect2, varscan2
- ZNF727 | c.1095G>C p.L365F | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV70701962, COSV70702291; called by muse, mutect2, varscan2
- ZYG11A | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1166564951, COSV65292334, COSV65293653; called by muse, mutect2, varscan2
- ACACA | c.6959G>T p.G2320V | Missense Mutation (SNP) | VAF 92/982 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); called by muse, mutect2
- ACACA | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- ACAN | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2
- AFDN | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AL121899.2 | c.297T>A p.S99R | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGPT2 | c.1438T>A p.S480T | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- AQP4 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- ARHGAP4 | c.2364C>G p.H788Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ATP8A1 | c.115A>C p.I39L | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2
- BIVM-ERCC5 | c.4307A>T p.K1436M | Missense Mutation (SNP) | VAF 69/750 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- C7orf31 | c.1743T>A p.Y581* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | called by muse, varscan2
- CACNA2D1 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 52/575 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- CARD10 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC168 | c.9638C>G p.S3213* | Nonsense Mutation (SNP) | VAF 34/423 reads (8%) | called by muse, mutect2
- CER1 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.059); called by muse, mutect2
- CHD1 | c.4318G>C p.E1440Q | Missense Mutation (SNP) | VAF 56/586 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); called by muse, mutect2
- CHST2 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CLK1 | c.180_223del p.S61Vfs*4 | Frame Shift Del (DEL) | VAF 109/774 reads (14%) | called by mutect2, pindel
- CNTN3 | c.2377A>T p.T793S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CNTN5 | c.1110A>T p.R370S | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- COG7 | c.937A>T p.R313W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- COL22A1 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- COQ4 | c.212C>A p.A71E | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPA4 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CR1L | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 80/892 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); called by muse, mutect2
- CSH2 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 44/1066 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2
- CSMD3 | c.7565G>T p.S2522I (on ENST00000297405 / NM_001363185.1; = p.S2418I on NM_052900.3) | Missense Mutation (SNP) | VAF 56/714 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- CUX2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.5468C>A p.S1823* | Nonsense Mutation (SNP) | VAF 52/711 reads (7%) | called by muse, mutect2
- DPP6 | c.971C>A p.P324H (on ENST00000377770 / NM_001364500.2; = p.P262H on NM_001936.5) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP8 | c.1625G>T p.G542V (on ENST00000341861 / NM_001320875.2; = p.G526V on NM_017743.6) | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DPP8 | c.1624G>T p.G542C (on ENST00000341861 / NM_001320875.2; = p.G526C on NM_017743.6) | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSPP | c.2809G>A p.D937N | Missense Mutation (SNP) | VAF 115/1400 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- ECHDC1 | c.287G>T p.W96L (on ENST00000531967 / NM_001139510.1; = p.W90L on NM_018479.3) | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- EHD3 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- EIF3H | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 78/485 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ESYT2 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- EYS | c.85del p.V29Wfs*13 | Frame Shift Del (DEL) | VAF 59/574 reads (10%) | called by mutect2, pindel, varscan2
- FAH | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FAM83H | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FAT1 | c.3732_3749del p.Q1244_Y1250delinsH | In Frame Del (DEL) | VAF 56/444 reads (13%) | called by mutect2, pindel
- FGD1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 64/155 reads (41%) | called by muse, mutect2, varscan2
- FOSB | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- GRID1 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRIK1 | c.2666G>T p.R889I (on ENST00000327783 / NM_001330994.2; = p.R874I on NM_001330993.2) | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- HELZ | c.5176C>T p.Q1726* | Nonsense Mutation (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
- HMBOX1 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- HMGCS1 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- HOXD12 | c.277G>T p.G93* | Nonsense Mutation (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- ICE1 | c.6716G>T p.R2239L | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IGKV1D-8 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 80/489 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGKV3D-15 | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 90/592 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- IGLV7-43 | c.269del p.G90Afs*5 | Frame Shift Del (DEL) | VAF 80/339 reads (24%) | called by mutect2, pindel, varscan2
- IGSF10 | c.2457G>C p.R819S | Missense Mutation (SNP) | VAF 40/782 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- IQSEC2 | c.896A>C p.Q299P (on ENST00000642864 / NM_001111125.3; = p.Q94P on NM_015075.2) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- ITPRID1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 41/648 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.415); called by muse, mutect2
- JAK2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KALRN | c.6554A>G p.N2185S (on ENST00000360013 / NM_001024660.4; = p.N488S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KAT6A | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 86/519 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KIAA0408 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 43/453 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF6 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- LCP2 | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- LRP1B | c.4643A>T p.H1548L | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRC37A3 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MAGEL2 | c.2960G>C p.S987T | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP4K5 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MDGA2 | c.1446del p.T483Rfs*5 (on ENST00000399232 / NM_001113498.2; = p.T185Rfs*5 on NM_182830.4) | Frame Shift Del (DEL) | VAF 79/428 reads (18%) | called by mutect2, pindel, varscan2
- MICAL1 | c.2704A>G p.T902A | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- MINDY3 | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MORC2 | c.1841G>T p.R614L (on ENST00000397641 / NM_001303256.3; = p.R552L on NM_014941.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MSH4 | c.2052T>G p.S684R | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MUC19 | c.446T>A p.L149Q | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5B | c.5819C>G p.T1940S | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYH15 | c.1613A>C p.K538T | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- NDST3 | c.2538C>A p.H846Q | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NDST4 | c.323T>A p.M108K | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NEB | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NLRP13 | c.1389G>T p.L463F | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NPY1R | c.335T>G p.M112R | Missense Mutation (SNP) | VAF 152/634 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NRK | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 119/437 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- NTRK1 | c.1211C>G p.S404C | Missense Mutation (SNP) | VAF 45/495 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.817); called by muse, mutect2
- NUDT12 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 47/524 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.403); called by muse, mutect2
- NYNRIN | c.4024_4028del p.S1342Lfs*58 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | called by mutect2, pindel
- OBSCN | c.16437G>T p.K5479N | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- OR11H1 | c.460G>C p.V154L | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by mutect2, varscan2
- OR13A1 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- OR5L2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PANK4 | c.820A>C p.S274R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- PCDH11Y | c.2627C>A p.A876D (on ENST00000400457 / NM_032973.2; = p.A865D on NM_032971.3) | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PCDHGA4 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- PIK3C2B | c.2584A>T p.S862C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PIWIL3 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 42/556 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- PKHD1L1 | c.2712G>C p.E904D | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLCH1 | c.4940T>A p.L1647H (on ENST00000340059 / NM_001130960.2; = p.L1639H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PLEKHH3 | c.848C>G p.P283R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLP1 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POU4F1 | c.228C>G p.F76L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, varscan2
- PPP1R9A | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 33/464 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP1R9A | c.1911T>A p.D637E | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PPP4R3C | c.2069G>C p.G690A | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PREX1 | c.3790G>T p.E1264* | Nonsense Mutation (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- PRICKLE3 | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PRND | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRPS2 | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by mutect2, varscan2
- PWWP2A | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- RAB19 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- REG3A | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- RELN | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RFC1 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 19/341 reads (6%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2
- RNF103 | c.1233G>C p.M411I | Missense Mutation (SNP) | VAF 44/469 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2
- ROS1 | c.3502G>T p.D1168Y | Missense Mutation (SNP) | VAF 105/635 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RXRA | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- RYR2 | c.5315G>C p.S1772T | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCUBE3 | c.2646G>T p.E882D | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SECISBP2L | c.1850T>A p.I617N (on ENST00000559471 / NM_001193489.2; = p.I572N on NM_014701.4) | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB3 | c.1010C>A p.T337K | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SH3GL2 | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 64/532 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC23A3 | c.111C>A p.D37E | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC25A13 | c.1636A>G p.T546A | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC3A1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC45A2 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- SMG1 | c.2243A>C p.Y748S | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TARM1 | c.226G>A p.E76K (on ENST00000616041 / NM_001330650.1; = p.E68K on NM_001135686.3) | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.124); called by muse, mutect2
- TBC1D8B | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBX18 | c.1629T>A p.S543R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TCAIM | c.693C>T p.I231= | Splice Region (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- THSD7B | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TMEFF2 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 57/493 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TP53BP1 | c.2312C>G p.S771C | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); called by muse, mutect2
- TTC3 | c.4301A>T p.N1434I | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- UACA | c.2545A>T p.T849S | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UBR4 | c.4868T>G p.V1623G | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- VPS13B | c.969A>T p.Q323H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- VWDE | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VXN | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- WDR49 | c.23A>G p.K8R (on ENST00000308378 / NM_001366158.1; = p.K349R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/676 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- WRN | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- WWC1 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); called by muse, mutect2
- XIRP2 | c.6191A>T p.N2064I (on ENST00000628543; = p.N2239I on NM_152381.6) | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZBTB45 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZBTB47 | c.1555_1557del p.K519del | In Frame Del (DEL) | VAF 35/193 reads (18%) | called by pindel, varscan2
- ZDBF2 | c.2058G>T p.E686D | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC2 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.339); called by muse, mutect2
- ZNF267 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF569 | c.2000G>A p.C667Y | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF569 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF578 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ZNF765 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 50/584 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.061); called by muse, mutect2
- ZNF813 | c.1570A>T p.K524* | Nonsense Mutation (SNP) | VAF 36/464 reads (8%) | called by muse, mutect2
- ZNF831 | c.4408C>G p.Q1470E | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ADCY3 | c.540C>T p.F180= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ALG12 | c.525G>A p.L175= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- ARAP3 | c.480C>T p.Y160= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as rs750850961; called by muse, mutect2
- ARFGEF2 | c.1515G>A p.R505= | Silent (SNP) | VAF 87/823 reads (11%) | called by muse, mutect2, varscan2
- BCKDHB | c.471T>C p.F157= | Silent (SNP) | VAF 92/554 reads (17%) | called by muse, mutect2, varscan2
- BIRC5 | c.243G>C p.S81= | Silent (SNP) | VAF 50/475 reads (11%) | catalogued as COSV56957351; called by muse, mutect2, varscan2
- C3 | c.2670C>T p.P890= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as rs137956083, COSV99837243; called by muse, mutect2
- CACNA1H | c.5295G>T p.A1765= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs529851125; called by muse, mutect2, varscan2
- CCDC186 | c.2169T>G p.R723= | Silent (SNP) | VAF 83/533 reads (16%) | called by muse, mutect2, varscan2
- DICER1 | c.252G>A p.Q84= | Silent (SNP) | VAF 22/624 reads (4%) | called by muse, mutect2
- DIPK1C | c.1002C>G p.V334= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- DOCK2 | c.5086C>A p.R1696= | Silent (SNP) | VAF 29/238 reads (12%) | catalogued as COSV56944050; called by muse, mutect2, varscan2
- DSP | c.7641C>T p.Y2547= | Silent (SNP) | VAF 180/669 reads (27%) | called by muse, mutect2, varscan2
- ERBB3 | c.1662G>A p.P554= | Silent (SNP) | VAF 54/501 reads (11%) | catalogued as rs754275955; called by muse, mutect2, varscan2
- F13A1 | c.2016A>G p.G672= | Silent (SNP) | VAF 138/817 reads (17%) | called by muse, mutect2, varscan2
- FAM47B | c.612C>A p.P204= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV61457433; called by muse, mutect2, varscan2
- FSIP2 | c.17868A>G p.E5956= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- GDI1 | c.675A>G p.L225= | Silent (SNP) | VAF 84/216 reads (39%) | catalogued as rs782173982, COSV50132646; called by muse, mutect2, varscan2
- GLMN | c.1128C>T p.P376= | Silent (SNP) | VAF 116/639 reads (18%) | called by muse, mutect2, varscan2
- GMPPA | c.333C>T p.F111= | Silent (SNP) | VAF 57/260 reads (22%) | catalogued as rs1199424948; called by muse, mutect2, varscan2
- GRIN2B | c.3078C>A p.G1026= | Silent (SNP) | VAF 21/182 reads (12%) | called by muse, mutect2, varscan2
- HMCN2 | c.936C>T p.N312= | Silent (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- IL25 | c.111C>G p.P37= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- IRAK1BP1 | c.222G>T p.V74= | Silent (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- KLHL42 | c.1149G>A p.K383= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, varscan2
- LCE1F | c.120C>T p.V40= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- LILRA2 | c.1380G>T p.L460= (on ENST00000391738 / NM_001130917.3; = p.L443= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/293 reads (20%) | catalogued as COSV99253443; called by muse, mutect2, varscan2
- LTK | c.2526T>C p.S842= | Silent (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2
- MAGEA11 | c.93C>A p.L31= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2
- MAGEC3 | c.477C>A p.V159= | Silent (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- MAGEL2 | c.699A>G p.P233= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- MCC | c.1701G>A p.Q567= | Silent (SNP) | VAF 25/299 reads (8%) | called by muse, mutect2
- MROH5 | c.828C>T p.S276= | Silent (SNP) | VAF 20/195 reads (10%) | called by muse, mutect2
- NEB | c.19371C>T p.I6457= | Silent (SNP) | VAF 42/286 reads (15%) | called by muse, mutect2, varscan2
- NLRP9 | c.423T>A p.A141= | Silent (SNP) | VAF 42/251 reads (17%) | called by muse, mutect2, varscan2
- NOD1 | c.255C>T p.F85= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- PARP12 | c.1938C>T p.A646= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- PCGF6 | c.669A>G p.K223= | Silent (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.9753C>T p.I3251= | Silent (SNP) | VAF 40/500 reads (8%) | catalogued as COSV61625293, COSV61629451; called by muse, mutect2
- PGM5 | c.1536C>T p.S512= | Silent (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- RAET1L | c.408T>C p.S136= | Silent (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.1599G>A p.V533= | Silent (SNP) | VAF 36/770 reads (5%) | catalogued as COSV50909391; called by muse, mutect2
- SF3B2 | c.1938C>T p.P646= | Silent (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- SIRPB2 | c.931C>T p.L311= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV63122871; called by muse, mutect2
- SLITRK2 | c.771G>A p.L257= | Silent (SNP) | VAF 68/225 reads (30%) | catalogued as rs782413822, COSV59425726; called by muse, mutect2, varscan2
- SOCS1 | c.186C>G p.A62= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100130200; called by muse, mutect2, varscan2
- SPACA1 | c.171G>A p.E57= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- SST | c.345C>G p.S115= | Silent (SNP) | VAF 40/435 reads (9%) | called by muse, mutect2
- STON1-GTF2A1L | c.2202T>A p.G734= | Silent (SNP) | VAF 43/421 reads (10%) | called by muse, mutect2, varscan2
- TACC3 | c.363A>G p.P121= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- TCHHL1 | c.213T>C p.D71= | Silent (SNP) | VAF 84/277 reads (30%) | catalogued as rs367938735; called by muse, mutect2, varscan2
- THAP2 | c.615C>A p.I205= | Silent (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- THBS3 | c.729G>A p.V243= | Silent (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- TRDN | c.1545A>G p.Q515= | Silent (SNP) | VAF 15/217 reads (7%) | catalogued as rs1232728917; called by muse, mutect2
- TRIM2 | c.369G>A p.G123= (on ENST00000437508; = p.G150= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs116331959; called by muse, varscan2
- TRIM50 | c.657G>A p.R219= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1968G>A p.E656= (on ENST00000580243 / NM_001308210.2; = p.E611= on NM_005786.6) | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- USP32 | c.657A>G p.T219= | Silent (SNP) | VAF 94/522 reads (18%) | catalogued as rs1276295178; called by muse, mutect2, varscan2
- VCAN | c.633G>T p.R211= | Silent (SNP) | VAF 127/1175 reads (11%) | catalogued as COSV54112647; called by muse, mutect2, varscan2
- WSB1 | c.912A>T p.I304= | Silent (SNP) | VAF 29/367 reads (8%) | called by muse, mutect2
- ZFPM2 | c.2070A>G p.E690= | Silent (SNP) | VAF 124/1098 reads (11%) | called by muse, mutect2, varscan2
- ZNF71 | c.1023C>T p.L341= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs771661534; called by muse, mutect2, varscan2
- ADGRD1 | c.1027-456G>T | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840059 T>C | 5'Flank (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- AL137060.6 | chr13:50082528 C>T | 3'Flank (SNP) | VAF 32/416 reads (8%) | catalogued as rs915709462; called by muse, mutect2
- CALHM6 | c.525+14G>T | Intron (SNP) | VAF 7/64 reads (11%) | catalogued as rs1353176234; called by muse, mutect2, varscan2
- CCDC138 | c.267-116A>C | Intron (SNP) | VAF 45/419 reads (11%) | called by muse, mutect2, varscan2
- CCDC191 | c.-5G>A | 5'UTR (SNP) | VAF 98/550 reads (18%) | called by muse, mutect2, varscan2
- CCDC88B | c.4375+10G>A | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs745658154; called by muse, mutect2
- CCKBR | c.811+76G>A | Intron (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- CDON | c.1198+10T>C | Intron (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.8547C>A | RNA (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552548 A>G | 3'Flank (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20985C>G | Intron (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- EIF5AL1 | chr10:79510588 G>T | 5'Flank (SNP) | VAF 30/454 reads (7%) | called by muse, mutect2
- GPM6A | c.37+24816A>G | Intron (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2, varscan2
- HNRNPU | c.987+14A>C | Intron (SNP) | VAF 61/428 reads (14%) | called by muse, mutect2, varscan2
- KCNMB2 | c.*245T>G | 3'UTR (SNP) | VAF 56/746 reads (8%) | called by muse, mutect2
- LRRC29 | chr16:67226977 C>T | 5'Flank (SNP) | VAF 18/72 reads (25%) | called by muse, varscan2
- MGAM | c.4618+1240C>A | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- MYT1L | c.*615T>C | 3'UTR (SNP) | VAF 33/451 reads (7%) | called by muse, mutect2
- NAMPTP1 | n.562G>T | RNA (SNP) | VAF 89/614 reads (14%) | called by muse, mutect2, varscan2
- NCAN | c.*86G>C | 3'UTR (SNP) | VAF 59/281 reads (21%) | called by muse, mutect2, varscan2
- NCDN | chr1:35557723 C>T | 5'Flank (SNP) | VAF 27/237 reads (11%) | catalogued as rs1229266943; called by muse, mutect2, varscan2
- OR56B3P | n.396C>A | RNA (SNP) | VAF 67/474 reads (14%) | catalogued as rs1409631183; called by muse, mutect2, varscan2
- OSBPL2 | c.674+731C>G | Intron (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- PACRG | c.613+102253G>C | Intron (SNP) | VAF 30/260 reads (12%) | called by muse, mutect2, varscan2
- RABGGTB | c.309+137G>A | Intron (SNP) | VAF 68/384 reads (18%) | catalogued as COSV100175011; called by muse, mutect2, varscan2
- RNU6-713P | chr12:40549927 T>A | 3'Flank (SNP) | VAF 38/437 reads (9%) | called by muse, mutect2
- XPNPEP2 | c.-16G>A | 5'UTR (SNP) | VAF 11/34 reads (32%) | catalogued as rs780038344, COSV64368149; called by mutect2, varscan2
- ZDHHC12 | c.101-68C>G | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- ZNF334 | c.22-1561A>G | Intron (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
